Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A8AY, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A8AY-01A (Primary Tumor).

[page 1 of 4]
Age: years Sex: Female

Print Date:

Date Collected:

Date Received:

Accession Number

Physician:

Copy to:

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist

Clinical Information

year old female with mesothelioma; Left Thoracotomy, Bronchoscopy, PDT, Total Pleurectomy

Final Diagnosis

1. PREVIOUS INCISION:

Skin and underlying soft tissue with changes consistent with previous site, no tumor seen.
Calretinin stain confirms absence of mesothelioma

2. RIB:

Bone with trilinear bone marrow formation and tenosynovial type soft tissue and fibromuscular soft tissue, no tumor seen.

3. PERIAORTIC TISSUE:

Fibrofatty soft tissue, no tumor seen.

4. LEVEL 5:

Sections of lymph node, no tumor seen.
CK5/6 stain confirms

5. PHRENIC NERVE:

Fibrofatty soft tissue with prominent peripheral nerve fibers and significant acute inflammation.
Fragment of soft tissue with presence of mesothelioma.

6. LEVEL 7:

Sections of lymph node, tumor present.
Calretinin stain confirms

7. LEVEL 5/6:

Sections of lymph node, no tumor seen.
CK5/6 stain confirms

8. POSTERIOR INTERCOSTAL:

Sections of lymph node, tumor present.
Calretinin stain confirms

9. PLEURA:

Mesothelioma, epithelioid type, closely associated but not invading lung tissue.
Tumor comes close to skeletal muscle.
No definite muscle invasion identified (9C).

ICD-O-3

Mesothelioma, epithelioid, malignant
9052/3

Site: Pleura NOS
0384

JFS 5/28/14

Name:
MRN:

[page 2 of 4]
[REDACTED]
[REDACTED]
[REDACTED] age: years Sex: Female

Print Date:
Date Collected:
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

The tumor is positive for D2-40, calretinin, AE1-3, CK5/6 and WT1 and negative for CEA, MOC 31 TTF1 and CD15, confirming presence of mesothelioma.

10. INTERLOBAR NODE:
Sections of lymph node, no tumor seen.
CK5/6 stain confirms

The case material was reviewed and the report verified by:
(Electronic signature)
Verification Date:

Note

Mesothelioma

Histologic Type
Epithelioid mesothelioma

Margins

Cannot be assessed

Lymph nodes

Specify: Number examined: 5 levels
Number involved: 2 levels

Pathologic Staging (pT3 N1 Mx)
Staging discussed with surgeon

Frozen Section Diagnosis

FS1: Scar: No tumor seen at area of skin scar marked by surgeon.

FS2: Periaortic Tissue: No tumor seen.

Dx Called To:

Name: [REDACTED]
MRN: [REDACTED]

[page 3 of 4]
Print Date:

Date Collected:

Date Received:

Accession No:

Physician:

Copy to:

Age: years Sex: Female

Surgical Pathology Report

Accession Number	Collection Date/Time	Received Date/Time	Verified Date/Time	Pathologist
------------------	----------------------	--------------------	--------------------	-------------

Gross Description

The case is received in 10 containers, each labeled with the patient's name and medical record number.

Specimen #1 is received fresh for frozen section, designated as "Previous Incision" and consists of a 12.3 x 0.6 cm skin ellipse excised to a depth of 1.2 cm. The skin surface is tan-white, wrinkled and slightly puckered. The specimen has been oriented by the surgeon with a stitch on an area of interest, which is submitted entirely for frozen section as FS1 and the frozen section control is submitted in cassette 1A. Additional representative sections of the remainder of the specimen are submitted in cassette 1B.

Specimen #2 is received in formalin, designated as "Rib" and consists of four cylindrical portions of rib ranging from 1.9 to 5.7 cm in length and averaging 1.2 cm in diameter. There is a moderate amount of attached red-brown, rubbery muscle. Sectioning reveals tan-red, trabeculated cut surfaces. No discrete masses are grossly identified. Representative sections are submitted in cassette 2A following decalcification.

Specimen #3 is received fresh for frozen section, designated as "Peri-Aortic Tissue" and consists of a 0.3 x 0.3 x 0.2 cm tan-white to tan-yellow, irregular soft tissue fragment, which is submitted entirely for frozen section as FS2 and the frozen section control is submitted in cassette 3A.

Specimen #4 is received in formalin, designated as "Level 5" and consists of a 1.2 x 0.9 x 0.9 cm gray-black, indurated, nodular soft tissue fragment, which is bisected to reveal gray-black, dense cut surfaces. The specimen is submitted entirely in cassette 4A.

Specimen #5 is received in formalin, designated as "Phrenic Nerve" and consists of two ragged and irregular to roughly cylindrical tan-grey, glistening soft tissue fragments measuring 2.9 and 15.7 cm in greatest dimension. The specimen is serially sectioned and submitted entirely in cassettes 5A and 5B.

Specimen #6 is received in formalin, designated as "Level 7" and consists of a 1.0 x 1.0 x 0.8 cm tan-gray, nodular soft tissue fragment, which is bisected to reveal tan-gray, dense cut surfaces. The specimen is submitted entirely in cassette 6A.

Specimen #7 is received in formalin, designated as "Level 5/6" and consists of a 3.6 x 2.2 x 0.9 cm fragment of tan-yellow adipose tissue, which incorporates four rubbery, possible lymph node ranging from 0.9 to 1.6 cm in greatest dimension. The specimen is submitted entirely in cassettes 7A.

Specimen #8 is received in formalin, designated as "Posterior Intercostal" and consists of three tan-yellow, irregular soft tissue fragments ranging from 0.3 to 1.7 cm in greatest dimension. The larger fragment is bisected to reveal tan-gray,

Name:

MRN:

[page 4 of 4]
Print Date:

Date Collected

Date Received:

Accession No

Physician:

Copy to:

Age: years Sex: Female

Surgical Pathology Report

Accession Number Collection Date/Time Received Date/Time Verified Date/Time Pathologist

glistening and cut surfaces. The larger fragment is submitted entirely in cassette 8A and the remaining two soft tissue fragments are submitted in toto in cassette 8B.

Specimen #9 is received in formalin, designated as "Pleura" and consists of a 25.7 x 12.7 x 5.8 cm ragged and irregular portion of tan-gray, firm tissue which have a moderate amount of attached red-brown, rubbery muscle, tan-white tendinous tissue and tan-yellow, lobulated adipose tissue. Sectioning reveals tan-white to tan-pink, firm, lobulated, glistening thickened areas, measuring up to 8.7 x 6.5 x 1.7 cm. Representative sections are submitted in cassettes 9A through 9E.

Specimen #10 is received in formalin, designated as "Interlobar Node" and consists of two tan-gray, rubbery, nodular to ragged and irregular soft tissue fragments measuring 1.9 and 3.7 cm in greatest dimension. The larger fragment incorporates four possible lymph nodes ranging from 1.2 to 2.2 cm in greatest dimension. Each possible lymph node is bisected and submitted entirely in cassettes 10A through 10E, respectively.

Dictated by:

Pathologist(s)

(Prior bx only)

HIV/AIDS Discrepancy		☒
Cause is Infectious		☒

Name

MRN

Source: NCI Genomic Data Commons file 82e28dc7-56fd-40f3-a721-b3eb4d6f1cb0 (TCGA-TS-A8AY.86750CA3-218B-4F37-BAB7-CCED5112C826.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).